Somatic mutation profile of tumor specimen 0DY447 from CCDI case PBCSEX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.0 years (4,002 days).
Specimen 0DY447: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97b3ee54-2199-48c4-af1f-b15a9736d4e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DY44J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cdfca64-3e21-4e3e-afa7-ca69c5c8a4ce

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYFIP1 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 60/928 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs374831208; called by muse, mutect2
- TTN | c.28976G>A p.G9659D (on ENST00000591111; = p.G8732D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/1684 reads (9%) | PolyPhen probably damaging (1); catalogued as rs1183241604, COSV100622110; called by muse, mutect2
- OBSCN | c.3959C>A p.A1320E | Missense Mutation (SNP) | VAF 41/411 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- H2BC11 | c.330C>T p.H110= | Silent (SNP) | VAF 184/682 reads (27%) | catalogued as rs1035755029; called by muse, mutect2, varscan2
- POTED | c.354C>T p.G118= | Silent (SNP) | VAF 51/443 reads (12%) | called by muse, mutect2, varscan2
- ENGASE | c.1815+39_1815+42del | Intron (DEL) | VAF 77/273 reads (28%) | called by mutect2, pindel, varscan2
